Gene-level copy-number profile of tumor specimen TCGA-36-2542-01A from TCGA case TCGA-36-2542, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 60.0 years (21,902 days).
Specimen TCGA-36-2542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.51555091-fa54-411f-9492-216557340bac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2542-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51a716da-3dad-499f-a753-c6d9a0008495

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 17,330; copy number 2: 31,826; copy number 3: 8,800; copy number 4: 1,047; copy number 5: 576; copy number 6: 179; copy number 8: 7; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2542-01A-01D-1043-01): tumor purity 0.75, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:123,216,339–123,637,093, 2 genes (within-gene range 0–1): TRDN, TRDN-AS1.
- chr14:106,599,670–106,875,071, 46 genes: IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV3-69-1, IGHV1-69-2, AC245369.21, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 644 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:77,157,207–77,433,388, 4 genes, copy number 5 (within-gene range 2–5): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr8:106,215,763–145,066,685, 578 genes, copy number 5–9 (broad region; genes not listed).
- chr12:114,104,542–114,105,931, 1 gene, copy number 6: GLULP5.
- chr15:80,663,772–81,518,200, 26 genes, copy number 6: RNU6-380P, ABHD17C, AC023302.1, AC023302.2, CEMIP, MIR549A, AC027808.1, AC027808.2, MESD, AC068870.1, MIR4514, AC068870.2, TLNRD1, AC068870.4, CFAP161, AC068870.3, ANP32BP3, IL16, AC103858.1, STARD5, AC103858.3, TMC3-AS1, TMC3, AC103858.2, KF456110.1, AC109809.1.
- chr17:67,774,591–68,551,319, 30 genes, copy number 5: RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A.
- chr20:45,534,196–45,547,752, 5 genes, copy number 5: WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN.

Autosomal genes at a single copy (total copy number 1): 17,330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
